Somatic mutation profile of tumor specimen TCGA-CR-7380-01A (aliquot TCGA-CR-7380-01A-11D-2012-08) from TCGA case TCGA-CR-7380, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 58.1 years (21,215 days).
Specimen TCGA-CR-7380-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bd7e054-0454-4e15-960a-442566fa5a42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7380-10A (Blood Derived Normal), aliquot TCGA-CR-7380-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4f5d6fc-60aa-42ee-9597-970960b74486

The open-access MAF lists 98 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 22, Nonsense Mutation 7, Frame Shift Ins 6, Frame Shift Del 3, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 18/23 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 20/28 reads (71%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 22/41 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VPS13B | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs180177354, CM041269, COSV62023690; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSS1 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as rs202004508, COSV60224099; called by muse, mutect2, varscan2
- AFF4 | c.1850C>G p.S617C | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV104373417, COSV99534742; called by muse, mutect2, varscan2
- ALOX15B | c.1697G>A p.W566* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as COSV101205589; called by muse, mutect2, varscan2
- C2orf16 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV101284360; called by muse, mutect2, varscan2
- CACNB1 | c.1659_1661del p.E553del | In Frame Del (DEL) | VAF 60/357 reads (17%) | catalogued as rs1254331025; called by pindel, varscan2
- CDH24 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 9/243 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99943645; called by muse, mutect2
- CEP126 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549081062, COSV99680821; called by muse, mutect2, varscan2
- CHD7 | c.2172T>A p.N724K | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV101418095; called by muse, mutect2, varscan2
- CMTM4 | c.643G>T p.V215L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100411757; called by muse, mutect2, varscan2
- COL22A1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100277277; called by muse, mutect2, varscan2
- COL3A1 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100482737; called by muse, mutect2, varscan2
- CPS1 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV51818842; called by muse, mutect2, varscan2
- CUX2 | c.4190C>T p.S1397L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs374715486; called by muse, mutect2, varscan2
- DCDC2 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1157188557, COSV65830785; called by muse, mutect2, varscan2
- DENND1B | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as COSV54156945; called by muse, mutect2, varscan2
- DLL4 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.38); catalogued as COSV99989702; called by muse, mutect2, varscan2
- ELAVL2 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); catalogued as COSV99805757; called by muse, mutect2, varscan2
- FRY | c.5452C>A p.Q1818K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV100968957, COSV66577743; called by muse, mutect2, varscan2
- HERC1 | c.8293C>T p.R2765W | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780612896, COSV101496443; called by muse, mutect2, varscan2
- HIP1R | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767656245, COSV99458486; called by muse, varscan2
- IL22RA1 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs748550168, COSV99582858; called by muse, mutect2, varscan2
- ITGB1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV56480972; called by muse, mutect2, varscan2
- KDM4B | c.3179G>A p.R1060H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99345956; called by muse, mutect2, varscan2
- KRT36 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.44); catalogued as rs771911925, COSV60202571; called by muse, mutect2, varscan2
- LEP | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100451385; called by muse, mutect2, varscan2
- LRRC8A | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as rs766650861, COSV52186934; called by muse, mutect2, varscan2
- LY75 | c.3808C>T p.Q1270* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99716208; called by muse, mutect2, varscan2
- MMP25 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100339384; called by muse, mutect2, varscan2
- MTARC2 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV63765596; called by muse, mutect2, varscan2
- NEDD9 | c.851C>A p.P284Q | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV101060807; called by muse, mutect2, varscan2
- NHP2 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51071087, COSV99200919; called by muse, mutect2, varscan2
- NOTCH1 | c.2677T>A p.C893S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99486466; called by muse, mutect2, varscan2
- NOTCH3 | c.4696G>A p.E1566K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.125); catalogued as COSV54650006; called by muse, mutect2, varscan2
- NRF1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as COSV99781670; called by mutect2, varscan2
- PHYHD1 | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100455012; called by muse, mutect2, varscan2
- PLCB1 | c.2966C>T p.T989M | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.353); catalogued as COSV62056618; called by muse, mutect2, varscan2
- PLXNB2 | c.4910A>G p.D1637G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833943; called by muse, mutect2, varscan2
- PRPF38B | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs1192046629, COSV100898236; called by muse, mutect2, varscan2
- PTPRF | c.5005C>T p.R1669W | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63444807; called by muse, mutect2, varscan2
- SERPINA1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.047); catalogued as COSV63346498; called by muse, mutect2, varscan2
- SFRP4 | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99554307; called by muse, mutect2, varscan2
- SLC22A11 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748923537, COSV100102221; called by muse, mutect2, varscan2
- SLC26A7 | c.1287dup p.Y430Ifs*6 | Frame Shift Ins (INS) | VAF 38/120 reads (32%) | catalogued as rs1453046666; called by mutect2, varscan2
- SLC38A10 | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs372430209, COSV99917318; called by muse, mutect2, varscan2
- SLC5A7 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50897890; called by muse, mutect2, varscan2
- SMAD9 | c.850C>T p.R284* (on ENST00000379826 / NM_001127217.3; = p.R247* on NM_005905.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as rs553369182, COSV100614534, COSV63206852; called by muse, mutect2, varscan2
- SORCS1 | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs767926672, COSV53839047; called by muse, mutect2, varscan2
- SPTBN1 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs975968980, COSV63336647; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.394A>G p.S132G | Missense Mutation (SNP) | VAF 26/98 reads (27%) | PolyPhen probably damaging (0.997); catalogued as COSV100082341; called by muse, mutect2, varscan2
- SUDS3 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101288531; called by muse, mutect2, varscan2
- TAF1L | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV54270963; called by muse, mutect2, varscan2
- TIA1 | c.473G>A p.W158* (on ENST00000433529 / NM_001351511.1; = p.W147* on NM_022037.4 and 9 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99248506; called by muse, mutect2, varscan2
- TMCC3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1407715240, COSV54154344, COSV99705330; called by muse, mutect2, varscan2
- TNFSF11 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs150392469; called by muse, mutect2, varscan2
- TNN | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs764490910, COSV99511503; called by muse, varscan2
- TOP3A | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1401508949, COSV100328983; called by muse, mutect2, varscan2
- TTN | c.96390C>A p.S32130R (on ENST00000591111; = p.S24706R on NM_003319.4) | Missense Mutation (SNP) | VAF 44/116 reads (38%) | PolyPhen probably damaging (0.999); catalogued as COSV100601989; called by muse, mutect2, varscan2
- TTN | c.16426G>A p.E5476K (on ENST00000591111; = p.E4549K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/194 reads (5%) | PolyPhen benign (0.011); catalogued as rs1287275902, COSV60171542; called by muse, mutect2
- TYW1 | c.2149dup p.D717Gfs*49 | Frame Shift Ins (INS) | VAF 11/50 reads (22%) | catalogued as rs1268216911; called by mutect2, pindel, varscan2
- WIPF1 | c.74T>G p.L25W | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99768290; called by muse, mutect2, varscan2
- XIRP2 | c.8724A>T p.Q2908H (on ENST00000628543; = p.Q3083H on NM_152381.6) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV99740607; called by muse, mutect2, varscan2
- ZNF212 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs145118937, COSV60026537, COSV60026555; called by muse, mutect2, varscan2
- ZNF831 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1383621842, COSV100925905; called by muse, mutect2, varscan2
- GALNT18 | c.991dup p.I331Nfs*54 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | called by mutect2, pindel
- LY75 | c.2796dup p.Y933Ifs*2 | Frame Shift Ins (INS) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- OR6C74 | c.304_305del p.T102Yfs*7 | Frame Shift Del (DEL) | VAF 42/244 reads (17%) | called by mutect2, pindel, varscan2
- PIBF1 | c.1482dup p.L495Ifs*10 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- RAET1E | c.749del p.N250Mfs*11 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | called by mutect2, pindel, varscan2
- SDC1 | c.92dup p.E32* | Frame Shift Ins (INS) | VAF 35/140 reads (25%) | called by mutect2, pindel, varscan2
- SLC1A3 | c.63_66del p.R23Nfs*50 | Frame Shift Del (DEL) | VAF 41/138 reads (30%) | called by mutect2, pindel, varscan2
- SMAP2 | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- AXIN1 | c.63C>T p.P21= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99249531, COSV99249690; called by muse, mutect2, varscan2
- CELSR1 | c.7155G>A p.P2385= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs775467507, COSV99417493; called by muse, mutect2, varscan2
- DAB2IP | c.906C>T p.A302= (on ENST00000408936; = p.A274= on NM_032552.3) | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs140379738; called by muse, mutect2, varscan2
- DCAF15 | c.795T>C p.S265= | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as COSV99585915; called by muse, mutect2, varscan2
- DDR1 | c.192G>A p.L64= | Silent (SNP) | VAF 72/227 reads (32%) | catalogued as COSV100241256; called by muse, mutect2, varscan2
- DNAH5 | c.951G>A p.A317= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as rs768621532, COSV99447175; called by muse, mutect2, varscan2
- GALP | c.213C>T p.A71= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV100627900; called by muse, mutect2, varscan2
- LILRA2 | c.1371C>T p.G457= (on ENST00000391738 / NM_001130917.3; = p.G440= on NM_006866.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- MFAP3 | c.375C>T p.F125= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as rs779575851, COSV59455533; called by muse, mutect2, varscan2
- MUC16 | c.33537C>A p.T11179= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV101199046; called by mutect2, varscan2
- MYO16 | c.2512T>C p.L838= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99193737; called by muse, mutect2, varscan2
- NAALADL2 | c.930G>A p.L310= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101380003; called by muse, mutect2
- NEXN | c.657C>G p.L219= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as rs762462350, COSV99630255; called by muse, mutect2, varscan2
- NOM1 | c.2496C>T p.H832= | Silent (SNP) | VAF 36/140 reads (26%) | catalogued as rs374634748; called by muse, mutect2, varscan2
- OBSL1 | c.3426C>T p.H1142= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs377322292; called by muse, mutect2, varscan2
- PASD1 | c.1059C>T p.G353= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100949209; called by muse, mutect2, varscan2
- PDILT | c.1467G>A p.L489= | Silent (SNP) | VAF 66/228 reads (29%) | catalogued as rs755749083, COSV100199220; called by muse, mutect2, varscan2
- SLC25A2 | c.90C>T p.F30= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs782057188, COSV53403460; called by muse, mutect2, varscan2
- STK31 | c.2205C>T p.P735= | Silent (SNP) | VAF 35/181 reads (19%) | catalogued as rs1390717386, COSV100669248; called by muse, mutect2, varscan2
- TSPAN15 | c.501G>A p.Q167= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100960279; called by muse, mutect2, varscan2
- ZNF362 | c.570C>T p.S190= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs1272226437, COSV65031536; called by muse, mutect2, varscan2
- ZNF670 | c.618C>T p.F206= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV63608993; called by muse, mutect2, varscan2
- SNORD115-3 | n.52A>C | RNA (SNP) | VAF 154/479 reads (32%) | called by muse, mutect2, varscan2
